Somatic mutation profile of tumor specimen TCGA-ZC-AAAH-01A (aliquot TCGA-ZC-AAAH-01A-11D-A428-09) from TCGA case TCGA-ZC-AAAH, project TCGA-THYM (Thymoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Thymoma, type B2, malignant; Tissue or organ of origin: Anterior mediastinum; Age at diagnosis: 52.4 years (19,146 days).
Specimen TCGA-ZC-AAAH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fba841bc-9b68-4d85-a5c6-ad7faf38f569.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ZC-AAAH-10A (Blood Derived Normal), aliquot TCGA-ZC-AAAH-10A-01D-A42B-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/530ba60d-c928-4f6c-a58b-f71e102014af

The open-access MAF lists 2 somatic variants for this specimen: 2 protein-altering or splice-affecting.
By variant classification: Missense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SLC24A4 | c.1700G>A p.G567D | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.605); catalogued as rs1418353912; called by muse, mutect2
- SYK | c.1160A>G p.K387R | Missense Mutation (SNP) | VAF 4/66 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.081); called by muse, mutect2
